Somatic mutation profile of tumor specimen TCGA-AG-3605-01A (aliquot TCGA-AG-3605-01A-01D-1989-10) from TCGA case TCGA-AG-3605, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IV; Age at diagnosis: 85.1 years (31,078 days).
Specimen TCGA-AG-3605-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd53e25e-d8a0-41e5-a369-6c6f64eeaadc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3605-10A (Blood Derived Normal), aliquot TCGA-AG-3605-10A-01W-1990-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f89e841-376f-44ba-9e22-4f119ee96164

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USP9X | c.5395C>T p.R1799* | Nonsense Mutation (SNP) | VAF 201/344 reads (58%) | catalogued as rs1555933937, COSV61073632; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MET | c.3362T>C p.V1121A | Missense Mutation (SNP) | VAF 239/416 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100577189; called by muse, mutect2, varscan2
- MPP2 | c.686G>A p.R229H (on ENST00000461854 / NM_001278372.2; = p.R205H on NM_005374.5) | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs766334508, COSV99290355; called by muse, mutect2, varscan2
- MYOD1 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.561); catalogued as COSV51454281; called by muse, mutect2, varscan2
- NDN | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs767312463, COSV59358381; called by muse, mutect2, varscan2
- PLA2G2F | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV100907910; called by muse, mutect2, varscan2
- RSPO1 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs201204537, COSV100740567; called by muse, mutect2, varscan2
- CAMK2A | c.1317C>T p.D439= (on ENST00000348628 / NM_171825.2; = p.D450= on NM_015981.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as rs373201434; called by muse, mutect2, varscan2
- FFAR4 | c.309C>T p.A103= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV101015703; called by muse, mutect2, varscan2
- PAPPA2 | c.4401C>T p.P1467= | Silent (SNP) | VAF 122/332 reads (37%) | catalogued as rs767738607, COSV100867997; called by muse, mutect2, varscan2
- SSTR4 | c.633C>T p.F211= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs746249628, COSV54798116; called by muse, varscan2
